FM case AD13045 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/80564b56-5ef1-4803-9ec8-f8ba83da50dd

Male, 56.0 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the small intestine; primary biopsied or resected from the duodenum. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
